Gene-level copy-number profile of tumor specimen TCGA-IN-A6RP-01A from TCGA case TCGA-IN-A6RP, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 63.7 years (23,282 days).
Specimen TCGA-IN-A6RP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.c35bbf42-7fd9-48e4-b84b-6fd0bdfcb70d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A6RP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62198137-623f-4649-b94d-e4c2a51890d3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 4,461; copy number 3: 24,823; copy number 4: 17,389; copy number 5: 9,876; copy number 6: 2,151; copy number 7: 737; copy number 8: 41; copy number 9: 113; copy number 10: 55; copy number 11: 22; copy number 12: 45; copy number 15: 13; copy number 17: 20; copy number 18: 2; copy number 23: 4; copy number 24: 57; copy number 27: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A6RP-01A-21D-A33S-01): tumor purity 0.48, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:53,480,825–53,581,107, 1 gene (within-gene range 0–2): LINC01917.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,111 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:67,991,684–76,007,509, 178 genes, copy number 7 (broad region; genes not listed).
- chr4:76,021,118–76,023,497, 1 gene, copy number 7 (within-gene range 4–7): CXCL10.
- chr4:82,900,684–84,299,189, 24 genes, copy number 7 (within-gene range 4–7): THAP9, LIN54, Y_RNA, RNU6-615P, COPS4, AC073840.1, PLAC8, AC114781.2, AC114781.3, AC114781.1, COQ2, HPSE, AC114781.5, AC114781.4, HELQ, MRPS18C, ABRAXAS1, SLC25A14P1, RPL30P5, GPAT3, Y_RNA, AC021192.1, AC079160.1, RNU6-774P.
- chr7:2,234,195–3,302,452, 25 genes, copy number 7: MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1.
- chr7:3,337,889–3,338,601, 1 gene, copy number 7: AC092427.1.
- chr7:13,854,355–15,842,360, 18 genes, copy number 7: AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1.
- chr7:29,912,528–32,762,924, 59 genes, copy number 7: AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1, CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR, ADCYAP1R1, AC006466.1, AC006398.1, AC006380.1, NEUROD6, AC005090.1, ITPRID1, PPP1R17, PDE1C, SNX2P2, AC018637.1, AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997.
- chr7:38,531,042–40,860,763, 35 genes, copy number 7: RN7SL83P, KRT8P20, FAM183BP, VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1, AC005160.1.
- chr7:46,261,064–49,259,846, 33 genes, copy number 8: AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2.
- chr7:120,746,738–124,027,659, 51 genes, copy number 7 (within-gene range 6–7): AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2.
- chr9:25,579,657–26,805,862, 9 genes, copy number 8–12: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1.
- chr11:69,438,365–73,598,189, 143 genes, copy number 9–15 (within-gene range 4–15) (broad region; genes not listed).
- chr11:76,444,923–80,327,911, 70 genes, copy number 10–24 (broad region; genes not listed).
- chr11:80,653,429–80,762,826, 2 genes, copy number 18: ARL6IP1P3, LINC02720.
- chr11:81,552,226–82,718,299, 6 genes, copy number 23–27 (within-gene range 3–27): MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr18:268,148–24,708,542, 456 genes, copy number 7–17 (within-gene range 5–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
